Somatic mutation profile of tumor specimen TCGA-DJ-A13V-01A (aliquot TCGA-DJ-A13V-01A-11D-A10S-08) from TCGA case TCGA-DJ-A13V, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 21.7 years (7,915 days).
Specimen TCGA-DJ-A13V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 384eab8f-92da-4f0e-8253-5dce2c21c8e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A13V-10A (Blood Derived Normal), aliquot TCGA-DJ-A13V-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df973cfe-656f-4d9d-9a6b-25a1311b5c14

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADAM11 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs370821656; called by muse, mutect2
- ALOXE3 | c.1550C>T p.A517V | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.23); catalogued as rs1289470540, COSV59075557; called by muse, mutect2, varscan2
- DNAJC13 | c.2590A>C p.T864P | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.638); catalogued as COSV53449922; called by muse, mutect2, varscan2
- FAM133A | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV59075149; called by muse, mutect2
- MCF2L2 | c.2370G>A p.K790= | Splice Region (SNP) | VAF 39/118 reads (33%) | catalogued as COSV61052965; called by muse, mutect2, varscan2
- TECTA | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs886047837, COSV50690989; ClinVar: uncertain significance; called by muse, mutect2
- MUC16 | c.41805G>A p.L13935= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs150582315, COSV66691705; called by muse, mutect2, varscan2
- NRIP1 | c.2385A>G p.L795= | Silent (SNP) | VAF 6/111 reads (5%) | catalogued as COSV59657119; called by muse, mutect2
